Somatic mutation profile of cancer-model specimen HCM-CSHL-0405-C25-85A (3D Organoid; aliquot HCM-CSHL-0405-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0405-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 48.3 years (17,648 days).
Specimen HCM-CSHL-0405-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54a81c3a-98ac-4b71-8e06-290c92935936.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0405-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0405-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e41e203-2fbf-44e1-8971-340fdb47f409

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Intron 3, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 208/464 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+2T>G p.X32_splice | Splice Site (SNP) | VAF 374/376 reads (99%) | hotspot (GDC flag); catalogued as COSV53738354; called by muse, mutect2, varscan2
- CBFA2T3 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 271/603 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs755685805; called by muse, mutect2, varscan2
- CEP104 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 197/400 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs755536798, COSV65517864; called by muse, mutect2, varscan2
- CLMN | c.2679_2681del p.E893del | In Frame Del (DEL) | VAF 84/224 reads (38%) | catalogued as rs1415417324; called by pindel, varscan2
- DHX37 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 364/808 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs368046437, COSV100438873, COSV104394572; called by muse, mutect2, varscan2
- DNASE1L3 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs773990318; called by muse, mutect2, varscan2
- DSTYK | c.2141A>G p.H714R | Missense Mutation (SNP) | VAF 251/438 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1553361152; called by muse, mutect2, varscan2
- LRFN1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 232/1783 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1568569338; called by muse, mutect2, varscan2
- NOS2 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 198/400 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375448100, COSV58227866; called by muse, mutect2, varscan2
- OR6N2 | c.769T>A p.F257I | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV59411274; called by muse, mutect2, varscan2
- PDGFRA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 239/521 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs779332376, COSV57271921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAG | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 181/418 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); catalogued as rs371502229, COSV68591185; called by muse, mutect2, varscan2
- SEMA5A | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 222/507 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs375422150; called by muse, mutect2, varscan2
- SP140L | c.660G>C p.W220C | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99707182; called by muse, mutect2
- TEX13B | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV57202560; called by muse, mutect2, varscan2
- TLCD4 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1250183068, COSV64632391; called by muse, mutect2, varscan2
- ANXA4 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 111/237 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCR2 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 148/192 reads (77%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2A | c.185_208del p.L62_E69del | In Frame Del (DEL) | VAF 648/1022 reads (63%) | called by mutect2, varscan2
- DIP2C | c.1948C>G p.P650A | Missense Mutation (SNP) | VAF 238/503 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FERMT2 | c.167_168del p.K56Rfs*4 | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | called by mutect2, pindel, varscan2
- IGHV3-13 | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 198/439 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KCTD14 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 132/503 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NAALAD2 | c.1493A>C p.N498T | Missense Mutation (SNP) | VAF 124/205 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOMO2 | c.1716G>T p.E572D | Missense Mutation (SNP) | VAF 233/667 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR5W2 | c.733T>G p.L245V | Missense Mutation (SNP) | VAF 244/506 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- PLCZ1 | c.1421G>T p.S474I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.097); called by muse, mutect2
- PTGER3 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- RASAL2 | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 181/405 reads (45%) | called by muse, mutect2, varscan2
- ROBO4 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 278/519 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIPA1L1 | c.3752C>A p.A1251D | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2
- SPTA1 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 778/1114 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- TDP1 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TTC21B | c.3461A>C p.K1154T | Missense Mutation (SNP) | VAF 294/701 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC13D | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 523/1056 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF493 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADAMTS16 | c.1770G>A p.S590= | Silent (SNP) | VAF 216/425 reads (51%) | catalogued as rs201912376, COSV56981644; called by muse, mutect2, varscan2
- CACNA1B | c.156C>T p.R52= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs1457654975; called by mutect2, varscan2
- FAM110B | c.135C>A p.P45= | Silent (SNP) | VAF 268/884 reads (30%) | called by muse, mutect2, varscan2
- GCN1 | c.1473C>T p.A491= | Silent (SNP) | VAF 242/457 reads (53%) | catalogued as rs200880565; called by muse, mutect2, varscan2
- IGDCC4 | c.474G>T p.G158= | Silent (SNP) | VAF 299/659 reads (45%) | called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.180C>T p.Y60= | Silent (SNP) | VAF 352/623 reads (57%) | catalogued as rs752509559, COSV61211545; called by muse, mutect2, varscan2
- INF2 | c.1179C>A p.A393= | Silent (SNP) | VAF 724/1510 reads (48%) | called by muse, mutect2, varscan2
- KRTAP19-4 | c.132C>T p.N44= | Silent (SNP) | VAF 372/714 reads (52%) | catalogued as rs766112768, COSV61858651; called by muse, mutect2, varscan2
- MRPS23 | c.66C>T p.A22= | Silent (SNP) | VAF 92/190 reads (48%) | catalogued as rs755842412, COSV100551451; called by muse, mutect2, varscan2
- SCN2A | c.4977G>A p.A1659= | Silent (SNP) | VAF 201/419 reads (48%) | catalogued as rs1250394077, COSV99333666; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDPCP | c.954C>A p.I318= | Silent (SNP) | VAF 79/188 reads (42%) | called by muse, mutect2, varscan2
- ZC3H4 | c.3882C>T p.F1294= | Silent (SNP) | VAF 70/70 reads (100%) | catalogued as rs541784925; called by muse, mutect2, varscan2
- C22orf34 | n.153C>T | RNA (SNP) | VAF 241/548 reads (44%) | catalogued as rs893078168; called by muse, mutect2, varscan2
- DEAF1 | c.289+26C>G | Intron (SNP) | VAF 27/34 reads (79%) | called by muse, mutect2, varscan2
- DENND5B | c.128-45083G>A | Intron (SNP) | VAF 97/290 reads (33%) | catalogued as rs1000397565; called by muse, mutect2, varscan2
- GRIK4 | c.907-2142G>A | Intron (SNP) | VAF 94/179 reads (53%) | catalogued as rs752888574; called by muse, mutect2, varscan2
